Somatic mutation profile of tumor specimen BA2308D (aliquot aq-BA2308D) from BEATAML1.0 case 2248, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,230 days).
Specimen BA2308D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec7428c9-b835-4c88-9932-890de9b842b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2215D (Solid Tissue Normal), aliquot aq-BA2215D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1318f594-7f75-46c3-a654-17aaae88e924

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs767009066; called by muse, mutect2, varscan2
- NUP107 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 64/129 reads (50%) | catalogued as COSV99971742; called by muse, mutect2, varscan2
- CHST2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM4 | c.2366-8T>G | Splice Region (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- MYH3 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 116/315 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- PKHD1L1 | c.4783del p.A1595Lfs*13 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, varscan2
- SLC13A3 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- VPS13B | c.3625G>A p.V1209I | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EIF3L | c.1185G>A p.G395= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- NMUR2 | c.489C>A p.A163= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV99676701; called by muse, mutect2
- USP11 | c.567C>T p.I189= (on ENST00000218348; = p.I146= on NM_001371072.1) | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
